Gene-level copy-number profile of tumor specimen TCGA-D1-A2G6-01A from TCGA case TCGA-D1-A2G6, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 53.5 years (19,547 days).
Specimen TCGA-D1-A2G6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.f03739c0-ba46-429b-a01a-6e68cadf3e57.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D1-A2G6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/97928e47-6a6c-40d4-8577-15490adf41b7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 44,237; copy number 3: 12,974; copy number 4: 2,604; copy number 6: 3; copy number 8: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D1-A2G6-01A-11D-A17C-01): tumor purity 0.6, ploidy 2.34, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:47,160,083–47,176,921, 1 gene, copy number 6: CALM2.
- chr2:47,225,781–47,240,886, 1 gene, copy number 6: AC073283.2.
- chr8:127,686,343–127,742,951, 2 genes, copy number 8 (within-gene range 3–8): CASC11, MYC.
- chr16:74,053,365–74,053,965, 1 gene, copy number 6: AC138627.2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
